Gene-level copy-number profile of tumor specimen HTMCP-02-03-01011-01A from CGCI case HTMCP-02-03-01011, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male.
Specimen HTMCP-02-03-01011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da881b67-bdcf-4637-b910-3a69c63c5922.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01011-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/0c97ed1f-955b-44ec-91eb-ebc37afe8bfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 5,615; copy number 2: 34,810; copy number 3: 16,523; copy number 4: 1,158; copy number 5: 165; copy number 6: 59; copy number 7: 13; copy number 8: 12; copy number 9: 3; copy number 13: 2; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:40,223,285–40,266,845, 2 genes (within-gene range 0–3): ANKRD20A2P, RNU6-1269P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 256 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,766,540–143,934,776, 11 genes, copy number 6: FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5.
- chr1:248,548,756–248,655,528, 10 genes, copy number 5: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr2:106,382,171–106,468,413, 2 genes, copy number 5: PLGLA, RGPD3.
- chr2:130,073,535–130,129,222, 1 gene, copy number 6 (within-gene range 4–6): POTEF.
- chr2:130,107,684–130,109,741, 2 genes, copy number 6: POTEF-AS1, RNU6-1049P.
- chr2:130,592,165–130,691,691, 4 genes, copy number 6–15 (within-gene range 2–15): CFC1, Metazoa_SRP, CYP4F30P, AC140481.3.
- chr2:131,218,067–131,265,278, 2 genes, copy number 5 (within-gene range 2–5): POTEE, RNU6-127P.
- chr4:49,203,171–49,246,915, 7 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr4:119,405,523–119,454,638, 3 genes, copy number 6: GTF2IP12, AC093752.3, RNU6-1217P.
- chr4:184,910,889–185,535,507, 20 genes, copy number 5: AC084871.2, MIR4455, AC112243.1, LINC02437, HELT, LINC02436, AC093824.1, AC093824.2, SLC25A4, CFAP97, SNX25, LRP2BP, AC112722.1, ANKRD37, UFSP2, Y_RNA, C4orf47, CCDC110, AC106897.1, PDLIM3.
- chr5:69,560,191–71,093,193, 29 genes, copy number 6: GTF2H2C, NAIPP3, AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1.
- chr7:56,805,336–57,074,664, 9 genes, copy number 5: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1.
- chr7:63,480,598–63,771,047, 9 genes, copy number 5: AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1, CICP24.
- chr7:74,773,962–75,031,528, 7 genes, copy number 6 (within-gene range 3–6): NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2.
- chr7:76,549,360–77,198,626, 20 genes, copy number 5 (within-gene range 3–5): AC004980.1, POMZP3, AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1.
- chr7:143,571,801–143,730,409, 7 genes, copy number 8: CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C.
- chr8:7,495,911–8,049,267, 41 genes, copy number 5: DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr9:40,346,144–40,806,344, 4 genes, copy number 6–7: CNN2P2, GXYLT1P3, AL591471.1, AL353626.1.
- chr9:66,082,350–66,085,031, 2 genes, copy number 13: SNX18P4, AL513478.1.
- chr10:50,150,603–50,152,287, 1 gene, copy number 5: SLC9A3P1.
- chr12:31,019,434–31,201,235, 5 genes, copy number 5: DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1.
- chr15:21,980,277–21,981,245, 1 gene, copy number 9: OR11J6P.
- chr15:28,362,796–28,392,018, 3 genes, copy number 5–8: AC091304.3, GOLGA8F, RN7SL238P.
- chr16:15,358,978–15,381,047, 2 genes, copy number 6: AC137803.1, NPIPA5.
- chr16:33,802,764–34,051,363, 20 genes, copy number 5: IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3.
- chr16:90,102,271–90,178,344, 1 gene, copy number 5 (within-gene range 2–5): FAM157C.
- chr16:90,110,574–90,222,851, 4 genes, copy number 5: AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:45,592,621–45,608,918, 3 genes, copy number 5: AC126544.1, MAPK8IP1P2, RPS26P8.
- chr17:46,274,784–46,757,464, 10 genes, copy number 7 (within-gene range 3–7): ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF.
- chr21:46,690,764–46,691,226, 1 gene, copy number 6: RPL23AP4.
- chr22:18,773,665–18,861,049, 5 genes, copy number 8–9: GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7.
- chr22:21,103,016–21,268,903, 10 genes, copy number 5: BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3.

Autosomal genes at a single copy (total copy number 1): 3,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
